Somatic mutation profile of tumor specimen 0DCYON from CCDI case PBBNEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.6 years (1,697 days).
Specimen 0DCYON: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c626cc3-612c-4027-9bb4-348693688ba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DCYOD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9618ece0-c796-4bcc-aea2-18ce49aaf64d

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 4, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 305/1415 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DICER1 | c.5532G>C p.K1844N | Missense Mutation (SNP) | VAF 48/1466 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1360182417; called by muse, mutect2
- ANK2 | c.206A>G p.H69R | Missense Mutation (SNP) | VAF 48/1148 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 53/1400 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- TBC1D12 | c.1395G>T p.L465= | Silent (SNP) | VAF 34/1348 reads (3%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 24/210 reads (11%) | called by muse, varscan2
- CALCOCO2 | c.825+77T>A | Intron (SNP) | VAF 25/205 reads (12%) | called by muse, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 8/133 reads (6%) | called by muse, mutect2
- LTBP4 | c.1627+64T>C | Intron (SNP) | VAF 8/74 reads (11%) | called by muse, mutect2
